Somatic mutation profile of tumor specimen TCGA-BR-8364-01A (aliquot TCGA-BR-8364-01A-11D-2340-08) from TCGA case TCGA-BR-8364, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.1 years (15,389 days).
Specimen TCGA-BR-8364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be7db53c-4c8c-4f01-89b4-bf0c01861cf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8364-10A (Blood Derived Normal), aliquot TCGA-BR-8364-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56099de6-d5aa-40de-9dbb-19af1c2ca835

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- CAP1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1158025127, COSV61223499; called by muse, mutect2, varscan2
- CDH1 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55733134; called by muse, mutect2, varscan2
- CEMIP | c.2986A>G p.I996V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54993007; called by muse, mutect2, varscan2
- IPPK | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55333940; called by muse, mutect2
- OR4X1 | c.757T>A p.S253T | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV60722961; called by muse, mutect2
- PCDHB12 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV53396851; called by muse, mutect2
- PHYHIP | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs199574600; called by mutect2, varscan2
- PLPPR3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs962268715, COSV62460054; called by muse, mutect2
- RIMS2 | c.4159C>T p.R1387* (on ENST00000666250 / NM_001348490.2; = p.R958* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs1324189515, COSV51683795; called by muse, mutect2, varscan2
- SGIP1 | c.1921A>G p.N641D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV52769351; called by muse, mutect2, varscan2
- TTBK1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs745618169, COSV52491503; called by muse, mutect2, varscan2
- SSX9P | n.349A>G | Splice Region (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- ZFHX3 | c.7231G>C p.A2411P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2
- COL28A1 | c.2851C>T p.L951= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV68082200; called by mutect2, varscan2
- COL5A1 | c.945G>A p.T315= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs149123775; ClinVar: likely benign; called by muse, mutect2, varscan2
